Somatic mutation profile of tumor specimen TCGA-BP-5195-01A (aliquot TCGA-BP-5195-01A-02D-1429-08) from TCGA case TCGA-BP-5195, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.4 years (27,547 days).
Specimen TCGA-BP-5195-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9d4ac90-2a2e-4daf-ad9f-6b37e61e852b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5195-11A (Solid Tissue Normal), aliquot TCGA-BP-5195-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c319629f-57ef-47a2-924b-4d947e0b0f3c

The open-access MAF lists 76 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 51, Silent 13, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs869025631, CD141834, CM951280, HM971583, COSV56542714, COSV56543921; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.075); catalogued as COSV65311053; called by muse, mutect2, varscan2
- ABCC9 | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV53966586; called by muse, mutect2, varscan2
- AMBN | c.745A>C p.N249H | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59825663; called by muse, mutect2
- AMER2 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs928807825, COSV63436853; called by muse, mutect2
- ANGPTL7 | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63869667; called by muse, mutect2, varscan2
- ANKRD30A | c.222-2A>G p.X74_splice (on ENST00000611781; = p.X18_splice on NM_052997.2) | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as rs1413241979, COSV64607570; called by muse, mutect2, varscan2
- ARAP2 | c.3512G>A p.R1171K | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100395005, COSV58284703; called by muse, mutect2
- ASH1L | c.8134A>G p.K2712E (on ENST00000368346 / NM_001366177.2; = p.K2707E on NM_018489.3) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV64206724; called by muse, mutect2, varscan2
- ATP8A2 | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54944955; called by muse, mutect2, varscan2
- CALM2 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as COSV55399058; called by muse, mutect2, varscan2
- CHIA | c.793C>A p.P265T (on ENST00000343320; = p.P157T on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58474552, COSV58475901; called by muse, mutect2, varscan2
- CHRNB1 | c.592C>A p.H198N | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV53439311; called by muse, mutect2
- CSMD3 | c.6745G>T p.E2249* (on ENST00000297405 / NM_001363185.1; = p.E2145* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 43/218 reads (20%) | catalogued as COSV52140872; called by muse, mutect2, varscan2
- CTNNA1 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV57072443; called by muse, mutect2, varscan2
- DGKZ | c.904G>A p.G302R (on ENST00000454345 / NM_001105540.2; = p.G113R on NM_003646.4) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58986659; called by muse, mutect2, varscan2
- FHL5 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV58736630; called by muse, mutect2, varscan2
- GPBP1 | c.1345A>G p.S449G | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV53310839; called by muse, mutect2, varscan2
- GTF3C5 | c.607A>G p.N203D | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59599351; called by muse, mutect2, varscan2
- GYPC | c.312T>G p.S104R | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52145745; called by muse, mutect2, varscan2
- HSPA8 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57083344; called by muse, mutect2, varscan2
- IFRD1 | c.993C>G p.D331E | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50043884; called by muse, mutect2
- ITGAL | c.816C>G p.N272K | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV63321138; called by muse, mutect2, varscan2
- ITSN2 | c.2160G>C p.Q720H | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.948); catalogued as COSV61945234; called by muse, mutect2, varscan2
- KCNH7 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59792019; called by muse, mutect2, varscan2
- KDM5C | c.865A>T p.K289* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV64763893; called by muse, mutect2, varscan2
- KLHL26 | c.548C>G p.S183W | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV56316742, COSV99963192; called by muse, mutect2, varscan2
- LRRC3 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as rs777833809, COSV52399088; called by muse, mutect2, varscan2
- LTBP1 | c.3220C>T p.H1074Y (on ENST00000404816 / NM_206943.4; = p.H748Y on NM_000627.4) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1334302954, COSV55377673; called by muse, mutect2
- MARF1 | c.1769G>T p.C590F | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV60021657; called by muse, mutect2, varscan2
- MEP1B | c.208A>G p.R70G | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52496542; called by muse, mutect2, varscan2
- MN1 | c.3662C>T p.A1221V | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV56557343, COSV56562978; called by muse, mutect2, varscan2
- MOV10L1 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV53169112; called by muse, mutect2, varscan2
- MTERF1 | c.908T>G p.L303R | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61098008; called by muse, mutect2, varscan2
- MTSS1 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1387337215, COSV61496048; called by muse, mutect2, varscan2
- MYOM1 | c.3043A>T p.N1015Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55288348; called by muse, mutect2
- OR4A15 | c.284G>C p.C95S | Missense Mutation (SNP) | VAF 87/384 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV59034291; called by muse, mutect2, varscan2
- OR52E4 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV57624289; called by muse, mutect2, varscan2
- PAFAH2 | c.1091A>C p.K364T | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV65339347; called by muse, mutect2, varscan2
- PBRM1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 121/399 reads (30%) | catalogued as COSV56268492; called by muse, mutect2, varscan2
- PITRM1 | c.228T>G p.Y76* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV56528623; called by muse, mutect2, varscan2
- PNLIP | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV65040041; called by muse, mutect2, varscan2
- PRSS21 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 90/558 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50051246; called by muse, mutect2, varscan2
- PTEN | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as CM1111461, COSV64293618, COSV64304198; called by muse, mutect2, varscan2
- RASSF9 | c.341T>G p.L114W | Missense Mutation (SNP) | VAF 59/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63433048; called by muse, mutect2, varscan2
- RSPH6A | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV55570929; called by muse, mutect2, varscan2
- SESTD1 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs202072498, COSV58930300; called by muse, mutect2, varscan2
- SNRNP48 | c.211T>A p.L71M | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV60939039; called by muse, mutect2, varscan2
- TRAPPC13 | c.501G>C p.Q167H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV51556962; called by muse, mutect2
- WASF2 | c.760T>A p.S254T | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV71005169; called by muse, mutect2, varscan2
- WRN | c.2567G>A p.G856D | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53298156; called by muse, mutect2, varscan2
- ZMYM2 | c.1748T>G p.I583S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV67033181; called by muse, mutect2, varscan2
- ZNF496 | c.623A>G p.Q208R | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV54175494; called by muse, mutect2
- ZNF804B | c.1590T>G p.D530E | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV60822233; called by muse, mutect2, varscan2
- BEST1 | c.1683_1686del p.N562Yfs*46 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by pindel, varscan2
- CHAT | c.858_872del p.Q287_V291del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- CISD2 | c.398A>G p.K133R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FAT3 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 73/298 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, varscan2
- KBTBD3 | c.930_931del p.T311Ifs*4 | Frame Shift Del (DEL) | VAF 31/181 reads (17%) | called by pindel, varscan2
- KDM5C | c.4187_4194del p.R1396Lfs*17 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- SBNO1 | c.3322_3325del p.N1108Efs*3 (on ENST00000420886; = p.N1107Efs*3 on NM_018183.5) | Frame Shift Del (DEL) | VAF 71/364 reads (20%) | called by mutect2, pindel, varscan2
- TTC32 | c.430del p.R144Efs*26 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- WNK3 | c.1215del p.F405Lfs*7 | Frame Shift Del (DEL) | VAF 8/87 reads (9%) | called by mutect2, pindel, varscan2
- AOC2 | c.903T>C p.S301= | Silent (SNP) | VAF 37/167 reads (22%) | catalogued as COSV53198609; called by muse, mutect2, varscan2
- ATRNL1 | c.1713A>G p.P571= | Silent (SNP) | VAF 61/250 reads (24%) | catalogued as COSV61801131; called by muse, mutect2, varscan2
- BCL2 | c.411C>T p.L137= | Silent (SNP) | VAF 26/132 reads (20%) | catalogued as COSV61376102; called by muse, mutect2, varscan2
- CDH8 | c.1239G>T p.V413= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV54857960; called by muse, mutect2, varscan2
- DST | c.6678C>G p.A2226= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as COSV99757431; called by muse, mutect2, varscan2
- GANC | c.2049G>A p.L683= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as COSV58808174; called by muse, mutect2, varscan2
- GOSR1 | c.648C>T p.N216= | Silent (SNP) | VAF 200/820 reads (24%) | catalogued as COSV56718569; called by muse, mutect2, varscan2
- KRTAP5-1 | c.582G>A p.K194= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs1472332126, COSV66298755, COSV66298861; called by muse, varscan2
- NYNRIN | c.1974A>T p.A658= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66841726; called by muse, mutect2, varscan2
- PRKCE | c.1833T>C p.N611= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV60315657; called by muse, mutect2, varscan2
- PSG3 | c.135T>A p.V45= | Silent (SNP) | VAF 80/420 reads (19%) | catalogued as COSV59503368; called by muse, mutect2, varscan2
- SERPINA9 | c.6A>G p.A2= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV54073820; called by muse, mutect2, varscan2
- SOX6 | c.849T>C p.A283= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as COSV57041774; called by muse, mutect2, varscan2
